Somatic mutation profile of tumor specimen ALCH-B1PZ-TTP1-A (aliquot ALCH-B1PZ-TTP1-A-1-0-D-A76Z-36) from ALCHEMIST case ALCH-B1PZ, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 60.5 years (22,087 days).
Specimen ALCH-B1PZ-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) df931a0e-815d-4d10-a8b8-cc98e6ff68a1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B1PZ-NB1-A (Blood Derived Normal), aliquot ALCH-B1PZ-NB1-A-1-0-D-A76Z-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/dc94ca30-993c-4635-84a2-0e1a7d14b500

The open-access MAF lists 47 somatic variants for this specimen: 33 protein-altering or splice-affecting, 10 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 24, Silent 10, Nonsense Mutation 4, 3'UTR 2, Splice Region 1, Intron 1, In Frame Del 1, Frame Shift Del 1, 5'Flank 1, Translation Start Site 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2127_2129del p.E709_T710delinsD | In Frame Del (DEL) | VAF 123/499 reads (25%) | hotspot (GDC flag); catalogued as rs397517086, COSV51779132; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- ANKRD17 | c.5924C>T p.S1975L | Missense Mutation (SNP) | VAF 18/538 reads (3%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.01); catalogued as COSV58220651; called by muse, mutect2
- APOB | c.13337G>T p.R4446I | Missense Mutation (SNP) | VAF 9/105 reads (9%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.447); catalogued as COSV51943767; called by muse, mutect2
- CARMIL2 | c.1876G>A p.A626T | Missense Mutation (SNP) | VAF 7/115 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1178879747; called by muse, mutect2
- CCDC40 | c.2551C>T p.R851W | Missense Mutation (SNP) | VAF 42/407 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs774273644, COSV100884311; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CRELD1 | c.914-7C>T | Splice Region (SNP) | VAF 31/193 reads (16%) | catalogued as rs200714636; called by muse, mutect2, varscan2
- CT47B1 | c.449G>A p.R150H | Missense Mutation (SNP) | VAF 19/291 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as rs1465740235, COSV64890358, COSV64890667; called by muse, mutect2
- EYA1 | c.1117_1118del p.H373Ffs*4 | Frame Shift Del (DEL) | VAF 18/132 reads (14%) | catalogued as rs886039674; called by pindel, varscan2
- FASTKD5 | c.1210C>T p.R404C | Missense Mutation (SNP) | VAF 16/149 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.65); catalogued as rs147076248; called by muse, mutect2, varscan2
- GUCA1A | c.394G>A p.A132T | Missense Mutation (SNP) | VAF 98/493 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.764); catalogued as rs1170053127, COSV50004986; called by muse, mutect2, varscan2
- MYH6 | c.4016G>A p.R1339Q | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.133); catalogued as rs766238876, COSV62450161; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SELP | c.2420G>T p.C807F | Missense Mutation (SNP) | VAF 12/101 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV55254634; called by muse, mutect2, varscan2
- SPTBN4 | c.6524G>A p.R2175Q | Missense Mutation (SNP) | VAF 14/116 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.258); catalogued as rs1027814678; called by muse, mutect2, varscan2
- ADAMTS20 | c.1588G>A p.D530N | Missense Mutation (SNP) | VAF 14/254 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ARMC2 | c.1380T>A p.D460E | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.492); called by muse, mutect2
- ASH2L | c.547C>T p.Q183* | Nonsense Mutation (SNP) | VAF 16/268 reads (6%) | called by muse, mutect2
- C6orf136 | c.901G>C p.G301R (on ENST00000376473 / NM_001109938.3; = p.G167R on NM_145029.4) | Missense Mutation (SNP) | VAF 14/286 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CCDC33 | c.1489C>G p.L497V | Missense Mutation (SNP) | VAF 24/284 reads (8%) | SIFT tolerated (0.58); PolyPhen benign (0.103); called by muse, mutect2
- CST2 | c.292C>A p.Q98K | Missense Mutation (SNP) | VAF 36/476 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.313); called by muse, mutect2
- DAAM1 | c.955A>C p.K319Q | Missense Mutation (SNP) | VAF 7/92 reads (8%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); called by muse, mutect2
- EPAS1 | c.1902A>C p.R634S | Missense Mutation (SNP) | VAF 13/122 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.424); called by muse, mutect2, varscan2
- GSC | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 25/187 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.276); called by muse, mutect2, varscan2
- MRC1 | c.1875C>A p.C625* | Nonsense Mutation (SNP) | VAF 14/234 reads (6%) | called by muse, mutect2
- MRPS9 | c.158C>T p.A53V | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.039); called by muse, mutect2
- MYBPC2 | c.898A>G p.S300G | Missense Mutation (SNP) | VAF 10/94 reads (11%) | SIFT tolerated (0.5); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- NR2E3 | c.349+2T>G p.X117_splice | Splice Site (SNP) | VAF 23/250 reads (9%) | called by muse, mutect2
- ODF4 | c.256G>T p.E86* | Nonsense Mutation (SNP) | VAF 39/297 reads (13%) | called by muse, mutect2, varscan2
- PRAMEF1 | c.749A>C p.E250A | Missense Mutation (SNP) | VAF 35/307 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.022); called by muse, varscan2
- PROS1 | c.1691C>A p.A564D | Missense Mutation (SNP) | VAF 7/111 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.015); called by muse, mutect2
- SAP30BP | c.661A>G p.I221V | Missense Mutation (SNP) | VAF 25/216 reads (12%) | SIFT tolerated (0.48); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- SIPA1L1 | c.3007G>T p.A1003S | Missense Mutation (SNP) | VAF 18/487 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2
- TNIP1 | c.1184T>G p.V395G | Missense Mutation (SNP) | VAF 98/312 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.311); called by muse, mutect2, varscan2
- TRAV7 | c.218C>A p.S73* | Nonsense Mutation (SNP) | VAF 18/258 reads (7%) | called by muse, mutect2
- ADAMTSL4 | c.2160C>A p.G720= | Silent (SNP) | VAF 18/135 reads (13%) | called by muse, mutect2, varscan2
- BATF | c.60A>G p.K20= | Silent (SNP) | VAF 31/304 reads (10%) | called by muse, mutect2
- CDYL2 | c.489T>C p.S163= | Silent (SNP) | VAF 26/352 reads (7%) | called by muse, mutect2
- GSTM4 | c.528C>T p.D176= | Silent (SNP) | VAF 85/425 reads (20%) | catalogued as rs781512791; called by muse, mutect2, varscan2
- KCNH1 | c.2346C>T p.L782= (on ENST00000271751 / NM_172362.3; = p.L755= on NM_002238.4) | Silent (SNP) | VAF 18/212 reads (8%) | catalogued as rs781750329; called by muse, mutect2
- KY | c.786G>A p.S262= | Silent (SNP) | VAF 24/219 reads (11%) | catalogued as rs374750857; called by muse, mutect2
- NPHP4 | c.3519C>A p.R1173= | Silent (SNP) | VAF 29/160 reads (18%) | called by muse, mutect2, varscan2
- SETDB1 | c.3009C>T p.S1003= | Silent (SNP) | VAF 10/182 reads (5%) | called by muse, mutect2
- SPTA1 | c.5157C>T p.F1719= | Silent (SNP) | VAF 32/359 reads (9%) | catalogued as COSV63753065; called by muse, mutect2
- WASHC4 | c.426A>G p.S142= | Silent (SNP) | VAF 28/253 reads (11%) | catalogued as rs775081464; called by muse, mutect2, varscan2
- ALG2 | c.*519A>G | 3'UTR (SNP) | VAF 20/194 reads (10%) | called by muse, mutect2
- BLOC1S5-TXNDC5 | c.372+39126T>A | Intron (SNP) | VAF 30/257 reads (12%) | called by muse, mutect2, varscan2
- SFR1 | chr10:104122106 G>T | 5'Flank (SNP) | VAF 22/209 reads (11%) | called by muse, mutect2
- SLC47A1 | c.*491G>T | 3'UTR (SNP) | VAF 11/294 reads (4%) | called by muse, mutect2
